Somatic mutation profile of tumor specimen ALCH-B1VD-TTP1-A (aliquot ALCH-B1VD-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1VD, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,914 days).
Specimen ALCH-B1VD-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41d5f274-eed1-465a-9bd1-c401c68a7c86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1VD-NB1-A (Blood Derived Normal), aliquot ALCH-B1VD-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44844c1d-3425-445a-800e-12f6b95f08ad

The open-access MAF lists 705 somatic variants for this specimen: 457 protein-altering or splice-affecting, 155 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 392, Silent 155, Intron 38, Nonsense Mutation 24, RNA 18, Frame Shift Del 14, 3'UTR 13, 5'UTR 11, Splice Site 10, 5'Flank 9, Splice Region 6, Frame Shift Ins 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEL2 | c.1761G>A p.W587* | Nonsense Mutation (SNP) | VAF 67/181 reads (37%) | catalogued as rs1566784441; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.10046C>T p.S3349L | Missense Mutation (SNP) | VAF 50/178 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as rs786205455, COSV63682165; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.3821G>T p.R1274L | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs199517408; called by muse, mutect2, varscan2
- ACSM2A | c.262G>T p.E88* (on ENST00000219054; = p.E9* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 70/527 reads (13%) | catalogued as COSV54581807; called by muse, mutect2, varscan2
- ACSM2B | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 37/106 reads (35%) | catalogued as COSV61656594; called by muse, mutect2, varscan2
- ADAMTS13 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 121/627 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63022494; called by muse, mutect2, varscan2
- ADRB2 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs1204500818; called by muse, mutect2, varscan2
- AGFG1 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100028576; called by muse, mutect2, varscan2
- ANK2 | c.8212G>C p.D2738H | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV100000849; called by muse, mutect2
- AOAH | c.107C>A p.S36* | Nonsense Mutation (SNP) | VAF 127/353 reads (36%) | catalogued as rs779347007; called by muse, mutect2, varscan2
- ARFGEF3 | c.3593G>T p.R1198L | Missense Mutation (SNP) | VAF 103/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52458598; called by muse, mutect2, varscan2
- ASH1L | c.8867G>A p.R2956Q (on ENST00000368346 / NM_001366177.2; = p.R2951Q on NM_018489.3) | Missense Mutation (SNP) | VAF 65/317 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs756414058, COSV64206037; called by muse, mutect2, varscan2
- ASIC5 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 20/108 reads (19%) | catalogued as rs866913666; called by muse, mutect2, varscan2
- ASTN2 | c.3866G>T p.R1289L (on ENST00000313400 / NM_001365069.1; = p.R1238L on NM_014010.5) | Missense Mutation (SNP) | VAF 159/463 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs139072409; called by muse, mutect2, varscan2
- ATAD2 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 128/228 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.09); catalogued as COSV54877239, COSV54882015; called by muse, mutect2, varscan2
- ATAD3C | c.864C>G p.I288M | Missense Mutation (SNP) | VAF 143/258 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66481506; called by muse, mutect2, varscan2
- ATP8B2 | c.2993C>T p.S998F (on ENST00000672630; = p.S965F on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59247659; called by muse, mutect2, varscan2
- AUTS2 | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1482454954, COSV100717284; called by muse, mutect2, varscan2
- AXIN2 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV100196835; called by muse, mutect2, varscan2
- BCORL1 | c.4473-2A>T p.X1491_splice | Splice Site (SNP) | VAF 69/105 reads (66%) | catalogued as COSV54404116; called by muse, mutect2, varscan2
- BHLHE41 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs767558663, COSV54378772; called by muse, mutect2, varscan2
- BIRC6 | c.7189A>G p.I2397V | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1244732170; called by muse, mutect2, varscan2
- BRPF3 | c.1652A>G p.Y551C | Missense Mutation (SNP) | VAF 69/193 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs781235767; called by muse, mutect2, varscan2
- C3orf20 | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV53783142; called by muse, mutect2, varscan2
- C9orf78 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1422862848; called by muse, mutect2, varscan2
- CABIN1 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54088329; called by muse, mutect2, varscan2
- CABS1 | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs759930150; called by muse, varscan2
- CENPB | c.1206G>C p.K402N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as COSV100713572, COSV60148605; called by muse, mutect2, varscan2
- CFAP47 | c.5483G>C p.C1828S | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV57973930; called by muse, mutect2, varscan2
- CFAP53 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 75/297 reads (25%) | catalogued as COSV101274990; called by muse, mutect2, varscan2
- CFAP61 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 48/582 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs553604373; called by muse, mutect2
- CFHR4 | c.1248C>A p.D416E (on ENST00000367416 / NM_001201551.2; = p.D170E on NM_006684.5) | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.841); catalogued as COSV52234473; called by muse, mutect2, varscan2
- CHD2 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 144/233 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67715954; called by muse, varscan2
- CIT | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs753256269; called by muse, mutect2, varscan2
- CNDP1 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.299); catalogued as rs746951731; called by muse, mutect2, varscan2
- CNGA1 | c.1973T>C p.V658A | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs548116727; called by muse, mutect2, varscan2
- CNTNAP5 | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV101443119; called by muse, mutect2, varscan2
- CTNND2 | c.1372+4T>A | Splice Region (SNP) | VAF 36/86 reads (42%) | catalogued as rs764244471; called by muse, mutect2, varscan2
- CYP2A13 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as COSV57837066; called by muse, mutect2, varscan2
- CYP2A13 | c.1178C>A p.P393H | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57838738; called by muse, mutect2, varscan2
- CYRIA | c.38A>T p.E13V | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100838215; called by muse, mutect2, varscan2
- DENND4A | c.5117G>A p.R1706H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.947); catalogued as rs757437909, COSV101475446; called by muse, mutect2
- DPYD | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 37/385 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs866869468; called by muse, mutect2
- DUSP2 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1384622163; called by muse, mutect2, varscan2
- EIF5B | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 76/400 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs1284650330; called by muse, mutect2, varscan2
- ENAM | c.2968C>A p.L990I | Missense Mutation (SNP) | VAF 140/474 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.465); catalogued as COSV68535889; called by muse, mutect2, varscan2
- EPHB2 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs778157217; called by muse, mutect2, varscan2
- ERICH3 | c.4511C>A p.T1504N | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV58599384; called by muse, mutect2, varscan2
- ERICH3 | c.1332G>C p.E444D | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV58612423; called by muse, mutect2, varscan2
- F8 | c.3155T>A p.L1052* | Nonsense Mutation (SNP) | VAF 39/63 reads (62%) | catalogued as CM123962; called by muse, mutect2, varscan2
- F9 | c.1244A>T p.H415L | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as CM940705; called by muse, mutect2, varscan2
- FAM155A | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65559809; called by muse, mutect2
- FBXO24 | c.1003C>T p.L335F (on ENST00000241071 / NM_033506.3; = p.L373F on NM_012172.5) | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs780556939; called by muse, mutect2, varscan2
- FLT1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as COSV56724980, COSV56736012; called by muse, mutect2, varscan2
- FSIP2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.21); catalogued as rs906304167; called by muse, mutect2, varscan2
- FSIP2 | c.9946C>A p.Q3316K | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1281967322; called by muse, mutect2, varscan2
- GAREM1 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as rs1199603325; called by muse, mutect2, varscan2
- GOLGA8N | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 164/654 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs773196024; called by muse, mutect2, varscan2
- GPAT2 | c.1915G>A p.A639T | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as COSV100853241, COSV100853359; called by muse, mutect2
- GRM3 | c.1600T>A p.C534S | Missense Mutation (SNP) | VAF 111/430 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64477931; called by muse, mutect2, varscan2
- HAUS8 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745670091; called by muse, mutect2, varscan2
- HCK | c.1246G>T p.G416W | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52944136; called by muse, mutect2, varscan2
- HDX | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.559); catalogued as COSV99946656; called by muse, mutect2, varscan2
- HECW1 | c.4730G>C p.R1577P | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434525710, COSV67842542; called by muse, mutect2, varscan2
- HGD | c.962G>C p.R321P | Missense Mutation (SNP) | VAF 75/451 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM098248; called by muse, mutect2, varscan2
- HGF | c.1244G>T p.W415L | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55946608, COSV55952188, COSV99737896; called by muse, mutect2, varscan2
- HOXC11 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 166/504 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as COSV54532911; called by muse, mutect2, varscan2
- HOXD12 | c.347G>T p.R116L | Missense Mutation (SNP) | VAF 123/480 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.469); catalogued as rs572921135; called by muse, mutect2, varscan2
- IFT81 | c.1500G>T p.K500N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs777336832; called by muse, varscan2
- IRF2BPL | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV99467607; called by muse, mutect2, varscan2
- ITK | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV70062606; called by muse, mutect2, varscan2
- JAKMIP2 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99508637; called by muse, mutect2
- JMJD4 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 53/240 reads (22%) | catalogued as rs770795482, COSV100247851; called by muse, mutect2, varscan2
- KCNH6 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 185/475 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs759261043; called by muse, mutect2, varscan2
- KIAA1217 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64599838; called by muse, mutect2, varscan2
- KLHL35 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.32); catalogued as COSV66219498, COSV66219637; called by muse, mutect2, varscan2
- KNTC1 | c.5153G>T p.W1718L | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100338030; called by muse, mutect2, varscan2
- KPNA6 | c.1537C>G p.P513A | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV65361693; called by muse, mutect2, varscan2
- KRT2 | c.535C>G p.R179G | Missense Mutation (SNP) | VAF 228/588 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59011699; called by muse, mutect2, varscan2
- KRT6C | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 240/664 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs763636809; called by muse, mutect2, varscan2
- LRCH4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 110/426 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377324041; called by muse, mutect2, varscan2
- LRRC4B | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750493069; called by muse, mutect2, varscan2
- LUC7L3 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV53589497; called by muse, mutect2
- MAGEC1 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 144/258 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV53570385; called by muse, mutect2, varscan2
- MARCO | c.813del p.P272Lfs*76 | Frame Shift Del (DEL) | VAF 59/199 reads (30%) | catalogued as COSV59054549, COSV59056687; called by mutect2, pindel, varscan2
- MEGF6 | c.5C>G p.S2W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.677); catalogued as rs770522758; called by muse, mutect2, varscan2
- MFAP2 | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 89/264 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as rs1231778940; called by muse, mutect2, varscan2
- MMP13 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 107/377 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV52823135; called by muse, mutect2, varscan2
- MRGPRF | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs778856837; called by muse, mutect2, varscan2
- MUC17 | c.1829C>A p.S610Y | Missense Mutation (SNP) | VAF 83/347 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV60303982; called by muse, mutect2, varscan2
- MXRA5 | c.6889C>T p.R2297C | Missense Mutation (SNP) | VAF 119/223 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777337988, COSV54245677; called by muse, mutect2, varscan2
- MYH8 | c.2254A>G p.I752V | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs762437428; called by muse, mutect2, varscan2
- MYLK3 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 85/325 reads (26%) | catalogued as rs1467037214; called by muse, varscan2
- NRXN2 | c.1904G>T p.G635V | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV55465582; called by muse, mutect2, varscan2
- OR2A14 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 197/544 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV68718024; called by muse, mutect2, varscan2
- OR2L2 | c.686C>G p.S229C | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63562789; called by muse, mutect2, varscan2
- OR2T1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100822252; called by muse, mutect2, varscan2
- OR51Q1 | c.49A>G p.T17A | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs113436707; called by muse, mutect2, varscan2
- OR52D1 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV59488535; called by muse, mutect2, varscan2
- OR5B3 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.035); catalogued as rs772280413; called by muse, mutect2, varscan2
- OR5L1 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.789); catalogued as rs61998198, COSV100450006, COSV61733363; called by muse, mutect2, varscan2
- OXTR | c.981G>C p.W327C | Missense Mutation (SNP) | VAF 214/393 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV57480000; called by muse, mutect2, varscan2
- PALLD | c.79T>C p.F27L | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs750580075; called by muse, mutect2, varscan2
- PARP8 | c.2341C>A p.Q781K | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs77746359; called by muse, mutect2, varscan2
- PCDH8 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400515624, COSV58815052; called by muse, mutect2, varscan2
- PCDHA1 | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV65374563, COSV65374814; called by muse, mutect2, varscan2
- PCDHGA6 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 101/249 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs975173370, COSV53975807, COSV54043909; called by muse, mutect2, varscan2
- PELI3 | c.1268C>G p.S423C | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100291961; called by muse, mutect2, varscan2
- PGM1 | c.811G>C p.D271H | Missense Mutation (SNP) | VAF 55/180 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1349011391; called by muse, mutect2, varscan2
- PIK3R5 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs370964753; called by muse, mutect2, varscan2
- PIM3 | c.86-8C>T | Splice Region (SNP) | VAF 35/77 reads (45%) | catalogued as rs1281381849; called by muse, mutect2, varscan2
- PLCH1 | c.2176C>T p.L726F (on ENST00000340059 / NM_001130960.2; = p.L738F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1206008728; called by muse, mutect2, varscan2
- PLG | c.1023A>T p.Q341H | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.065); catalogued as rs138051887; called by muse, mutect2, varscan2
- PNPLA7 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs777428356, COSV52997971, COSV53005669, COSV99479812; called by muse, mutect2, varscan2
- PPCS | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 38/633 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs772504440; called by muse, mutect2
- PRAMEF12 | c.1192del p.R398Afs*6 | Frame Shift Del (DEL) | VAF 79/629 reads (13%) | catalogued as COSV100743080; called by mutect2, pindel, varscan2
- PSME4 | c.5400G>A p.M1800I | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.627); catalogued as rs747313182; called by muse, mutect2, varscan2
- PTPRD | c.4861C>A p.P1621T | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1330364871, COSV61939890; called by muse, mutect2, varscan2
- QKI | c.1012G>T p.A338S | Missense Mutation (SNP) | VAF 129/410 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.108); catalogued as COSV51692094; called by muse, mutect2, varscan2
- RALGAPA2 | c.1975G>C p.E659Q | Missense Mutation (SNP) | VAF 57/638 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs377420359; called by muse, mutect2
- RBM33 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as rs762099807; called by muse, mutect2, varscan2
- RBM33 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.017); catalogued as rs761329600; called by muse, mutect2
- RGS6 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100666520; called by muse, mutect2, varscan2
- RNF215 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.249); catalogued as rs751886907; called by muse, mutect2, varscan2
- RPE65 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 130/629 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs893611409; called by muse, mutect2, varscan2
- SALL3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1226720509, COSV73306115; called by muse, mutect2, varscan2
- SCARB1 | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 110/297 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs1223218413; called by muse, mutect2, varscan2
- SEH1L | c.527G>C p.R176P | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV50816350; called by muse, mutect2, varscan2
- SH3GLB1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65281030; called by muse, mutect2, varscan2
- SIX3 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99578437; called by mutect2, varscan2
- SLC24A3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 39/225 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV100040561; called by muse, mutect2, varscan2
- SLC7A13 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 143/224 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV52533072; called by muse, mutect2, varscan2
- SLCO1B1 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57011701; called by muse, mutect2
- SOX11 | c.903del p.T302Pfs*60 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | catalogued as COSV58984561; called by mutect2, pindel, varscan2
- SPAG17 | c.2153G>A p.R718K | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs779688185; called by muse, mutect2, varscan2
- SPATA4 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as rs1347986554; called by muse, mutect2, varscan2
- SPEF2 | c.3372G>T p.K1124N | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100606223; called by muse, mutect2, varscan2
- SRP9 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1438938430, COSV59158683; called by muse, mutect2
- SSX2IP | c.408C>G p.S136R | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as rs993107023; called by muse, mutect2
- SYCE1 | c.694C>T p.R232C (on ENST00000343131 / NM_001143764.3; = p.R196C on NM_130784.3) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs566597399, COSV58218434; called by muse, mutect2, varscan2
- TC2N | c.1414G>C p.E472Q | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs775189452; called by muse, mutect2, varscan2
- TCEAL6 | c.112G>C p.A38P | Missense Mutation (SNP) | VAF 137/284 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as COSV101036042, COSV65654008, COSV65654099; called by muse, mutect2, varscan2
- TIGD4 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99079674; called by muse, mutect2, varscan2
- TMPO | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 26/296 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1484986772, COSV99702145; called by muse, mutect2
- TRGV3 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 78/233 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs1253953005; called by muse, mutect2, varscan2
- TSGA10 | c.2036G>T p.R679L | Missense Mutation (SNP) | VAF 147/357 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61822852; called by muse, mutect2, varscan2
- USH2A | c.5736del p.E1913Sfs*19 | Frame Shift Del (DEL) | VAF 71/358 reads (20%) | catalogued as CD159138; called by mutect2, pindel, varscan2
- WDR3 | c.2470C>G p.L824V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60468255; called by muse, mutect2, varscan2
- XIRP2 | c.1547C>T p.T516I (on ENST00000628543; = p.T691I on NM_152381.6) | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1316719849, COSV54729246; called by muse, mutect2, varscan2
- ZNF264 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.125); catalogued as rs753183718, COSV54040847, COSV54041496; called by muse, mutect2, varscan2
- ZNF304 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 59/134 reads (44%) | catalogued as COSV56586660; called by muse, mutect2, varscan2
- ZNF469 | c.9367C>T p.R3123C (on ENST00000437464; = p.R3151C on NM_001367624.2) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755567767; called by muse, mutect2, varscan2
- ZNF81 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100095826; called by muse, mutect2, varscan2
- AADACL4 | c.629C>G p.S210* | Nonsense Mutation (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
- ABCA12 | c.1158C>A p.D386E (on ENST00000272895 / NM_173076.3; = p.D68E on NM_015657.3) | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA4 | c.6598G>T p.E2200* | Nonsense Mutation (SNP) | VAF 151/800 reads (19%) | called by muse, mutect2, varscan2
- ABLIM1 | c.1415G>T p.R472L | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AC068580.4 | c.656T>G p.M219R | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ACSM2A | c.737C>A p.A246D (on ENST00000219054; = p.A167D on NM_001308169.2) | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ADA2 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- ADGRA1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 101/313 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ADGRB3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- ADGRL3 | c.3400G>C p.E1134Q (on ENST00000506720 / NM_001322402.2; = p.E1066Q on NM_015236.6) | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADH1C | c.1107C>G p.I369M | Missense Mutation (SNP) | VAF 40/260 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- AGFG1 | c.1206C>T p.S402= | Splice Region (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- AHNAK | c.10255G>A p.D3419N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKAP3 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ALG8 | c.1387T>A p.Y463N | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANAPC5 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ANKRD11 | c.2203G>C p.E735Q | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ANKRD13A | c.41A>T p.H14L | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKRD26 | c.3251G>T p.R1084I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- ANLN | c.2192A>T p.Q731L | Missense Mutation (SNP) | VAF 79/224 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO8 | c.1845G>C p.K615N | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ANXA6 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AP2A2 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- APBA2 | c.42G>C p.L14F | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- APP | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 151/452 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ARHGAP21 | c.1940A>G p.K647R | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATP2B1 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATP7A | c.1980C>A p.F660L | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AVPR1A | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- BARHL2 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 181/562 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BCHE | c.1521T>A p.N507K | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- BOP1 | c.1864_1874del p.W622Pfs*8 | Frame Shift Del (DEL) | VAF 41/298 reads (14%) | called by mutect2, pindel, varscan2
- C1orf167 | c.1285del p.Q429Sfs*96 | Frame Shift Del (DEL) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- C1orf94 | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2
- C4orf45 | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- C5 | c.2105G>C p.G702A | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1E | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CARMIL2 | c.1438A>C p.R480= | Splice Region (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- CARS1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 48/311 reads (15%) | called by muse, mutect2, varscan2
- CC2D2A | c.4075G>C p.D1359H | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- CCDC137 | c.255G>C p.K85N | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CCL25 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CCNB3 | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CDH20 | c.1137T>A p.S379R | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- CDH26 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.113); called by muse, varscan2
- CEBPZ | c.26A>T p.E9V | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CEP295 | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 67/199 reads (34%) | called by muse, mutect2, varscan2
- CHD1 | c.1112T>G p.V371G | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, varscan2
- CHRNB2 | c.1038_1039insGCAG p.L347Afs*24 | Frame Shift Ins (INS) | VAF 84/406 reads (21%) | called by mutect2, pindel*, varscan2*
- CKS1B | c.40G>C p.D14H | Missense Mutation (SNP) | VAF 51/425 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CLCA4 | c.1060A>G p.T354A | Missense Mutation (SNP) | VAF 61/225 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CLIP1 | c.1459G>C p.E487Q (on ENST00000620786 / NM_001247997.1; = p.E476Q on NM_002956.2) | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLMN | c.2458G>A p.E820K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CMYA5 | c.3959C>G p.S1320C | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CMYA5 | c.5972C>G p.P1991R | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- CNTN4 | c.1943-1G>T p.X648_splice | Splice Site (SNP) | VAF 38/544 reads (7%) | called by muse, mutect2
- CNTNAP1 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 41/293 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL8A2 | c.1217G>A p.G406E | Missense Mutation (SNP) | VAF 145/419 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- COP1 | c.760del p.A254Qfs*33 | Frame Shift Del (DEL) | VAF 11/65 reads (17%) | called by mutect2, pindel*, varscan2*
- COPS3 | c.1179G>T p.M393I | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2
- CPSF1 | c.1771G>T p.E591* | Nonsense Mutation (SNP) | VAF 32/136 reads (24%) | called by muse, mutect2, varscan2
- CRACR2A | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 34/197 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRAMP1 | c.3347C>G p.P1116R | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CSN3 | c.269A>T p.H90L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CYP1B1 | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CYP1B1 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CYP2C18 | c.1451A>C p.Q484P | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DCTN1 | c.1555A>C p.K519Q | Missense Mutation (SNP) | VAF 108/819 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DGUOK | c.350G>T p.S117I | Missense Mutation (SNP) | VAF 82/654 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX35 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DHX40 | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DIP2A | c.3102G>A p.M1034I | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DLC1 | c.1903G>T p.D635Y (on ENST00000276297 / NM_001348081.2; = p.D198Y on NM_006094.5) | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DNAAF6 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- DNAH17 | c.4415T>G p.V1472G | Missense Mutation (SNP) | VAF 32/362 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- DNAH6 | c.2214T>G p.D738E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- DNAH7 | c.2284G>C p.G762R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP6 | c.1249del p.V417Sfs*71 (on ENST00000377770 / NM_001364500.2; = p.V355Sfs*71 on NM_001936.5) | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | called by mutect2, pindel, varscan2
- EHD4 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EP400 | c.5110G>T p.E1704* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | called by muse, mutect2, varscan2
- EPB42 | c.1730G>A p.C577Y (on ENST00000441366 / NM_001114134.2; = p.C607Y on NM_000119.3) | Missense Mutation (SNP) | VAF 185/459 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EPHA10 | c.1420T>C p.W474R | Missense Mutation (SNP) | VAF 80/341 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ERBB3 | c.2405A>T p.H802L | Missense Mutation (SNP) | VAF 177/520 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ERVV-2 | c.1208A>T p.N403I | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ESPN | c.1150T>A p.S384T | Missense Mutation (SNP) | VAF 108/755 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ESRRA | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- ETAA1 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EXOSC10 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- FAM171B | c.724G>C p.G242R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM187A | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- FBN2 | c.7878C>G p.H2626Q | Missense Mutation (SNP) | VAF 145/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FBXL6 | c.1163dup p.L388Ffs*67 | Frame Shift Ins (INS) | VAF 126/337 reads (37%) | called by mutect2, pindel, varscan2
- FHL2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- FLG | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 137/475 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FREM1 | c.431T>G p.V144G | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLI1 | c.991T>C p.Y331H | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLTPD2 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1471C>G p.Q491E | Missense Mutation (SNP) | VAF 146/505 reads (29%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.007); called by muse, varscan2
- GOLGA6L6 | c.437del p.G146Efs*6 | Frame Shift Del (DEL) | VAF 58/182 reads (32%) | called by mutect2, varscan2
- GOLGB1 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- GPR32 | c.92C>G p.S31C | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRID1 | c.1778G>T p.S593I | Missense Mutation (SNP) | VAF 59/319 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GRIN2B | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- GRIN2C | c.1675_1677del p.M559del | In Frame Del (DEL) | VAF 58/272 reads (21%) | called by pindel, varscan2
- HCN3 | c.711C>G p.I237M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- HERC5 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC5 | c.2845C>A p.L949M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIVEP3 | c.5639A>C p.E1880A | Missense Mutation (SNP) | VAF 115/240 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HMCN1 | c.3734A>C p.N1245T | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN2 | c.10405G>C p.E3469Q | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- HNRNPF | c.115G>T p.G39W | Missense Mutation (SNP) | VAF 53/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA6 | c.1506G>C p.K502N | Missense Mutation (SNP) | VAF 107/377 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HUS1B | c.340del p.V114Wfs*52 | Frame Shift Del (DEL) | VAF 48/120 reads (40%) | called by mutect2, pindel, varscan2
- IDE | c.52C>A p.R18S | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHMBP2 | c.396_413del p.N132_L137del | In Frame Del (DEL) | VAF 39/325 reads (12%) | called by mutect2, pindel, varscan2
- IKBKE | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- IL1R2 | c.571C>G p.H191D | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- IMPG2 | c.3166C>G p.L1056V | Missense Mutation (SNP) | VAF 53/503 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- IRS1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- JAKMIP1 | c.2173C>G p.L725V | Missense Mutation (SNP) | VAF 202/584 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KANSL1L | c.932A>T p.N311I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KAT6B | c.4318G>C p.E1440Q | Missense Mutation (SNP) | VAF 148/636 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KCNK6 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 56/284 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KDM2B | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF11 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- KIF14 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- KIF21A | c.4161del p.N1388Tfs*6 (on ENST00000361418 / NM_001378440.1; = p.N1375Tfs*6 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 84/287 reads (29%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); called by muse, varscan2
- KLHL2 | c.1028G>T p.R343M | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL6 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KLK3 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- KMT2A | c.3410G>C p.R1137T | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KMT2C | c.3383A>T p.D1128V | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KPNA2 | c.1280A>T p.N427I | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- KRT10 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, varscan2
- KRT85 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 284/927 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- LEPR | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP4 | c.4816G>C p.V1606L | Missense Mutation (SNP) | VAF 79/472 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LRRIQ1 | c.1103dup p.N369Efs*30 | Frame Shift Ins (INS) | VAF 19/71 reads (27%) | called by mutect2, varscan2
- LRRK2 | c.7028+1G>A p.X2343_splice | Splice Site (SNP) | VAF 10/116 reads (9%) | called by muse, mutect2
- LRRN2 | c.1081C>A p.L361M | Missense Mutation (SNP) | VAF 96/324 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYAR | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MAGEA6 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 162/289 reads (56%) | called by muse, mutect2, varscan2
- MALRD1 | c.6262C>G p.H2088D | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- METTL11B | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 67/255 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLLT6 | c.78T>G p.D26E | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MMP24 | c.314A>C p.K105T | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MPP3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- MPP5 | c.1199A>T p.N400I | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- MUC17 | c.2482A>T p.T828S | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MUC19 | c.1384C>A p.H462N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.223); called by muse, varscan2
- MYO15A | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYO7A | c.4441G>T p.G1481C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, varscan2
- NAV3 | c.4535A>G p.Y1512C | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBPF14 | c.3681G>T p.E1227D | Missense Mutation (SNP) | VAF 20/818 reads (2%) | SIFT tolerated (0.09); PolyPhen benign (0.388); called by muse, mutect2
- NDRG3 | c.240G>A p.M80I (on ENST00000349004 / NM_032013.4; = p.M68I on NM_022477.4) | Missense Mutation (SNP) | VAF 81/269 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NDUFS3 | c.520T>C p.F174L | Missense Mutation (SNP) | VAF 97/547 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- NEFH | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- NELL1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 80/412 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- NFXL1 | c.1736A>G p.H579R | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRC5 | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NLRP10 | c.1022T>C p.V341A | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- NLRP14 | c.2025G>T p.L675F | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- NLRP8 | c.2596A>C p.S866R | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NPEPPS | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated, low confidence (0.9); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- NPLOC4 | c.292A>G p.K98E | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR1H4 | c.597G>C p.E199D (on ENST00000551379 / NM_001206993.2; = p.E189D on NM_005123.4) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.41); called by muse, mutect2
- NRG1 | c.1774C>A p.Q592K (on ENST00000405005 / NM_013964.5; = p.Q597K on NM_013956.5) | Missense Mutation (SNP) | VAF 176/340 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- NRXN1 | c.2630T>G p.M877R | Missense Mutation (SNP) | VAF 115/311 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NRXN1 | c.1825C>A p.L609M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NSMCE3 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 136/379 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NT5C | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NT5DC4 | c.342G>T p.R114S | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.787); called by muse, mutect2
- NTRK2 | c.2363G>C p.G788A (on ENST00000323115 / NM_001369534.1; = p.G804A on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NYX | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 186/319 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OLFM3 | c.878C>A p.T293N (on ENST00000338858 / NM_001288821.1; = p.T273N on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/291 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR10G4 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- OR11H2 | c.538C>G p.H180D (on ENST00000556246; = p.H191D on NM_001197287.1) | Missense Mutation (SNP) | VAF 120/1851 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2
- OR4C3 | c.542C>A p.P181H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR52R1 | c.389G>C p.C130S | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR5H6 | c.342G>T p.M114I (on ENST00000642105; = p.M98I on NM_001005479.2) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- OR5I1 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OR5R1 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, varscan2
- OR6C3 | c.139T>A p.F47I | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR6Q1 | c.379T>A p.Y127N | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PATL2 | c.250A>G p.K84E | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- PCDH7 | c.3069T>G p.D1023E | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PDE9A | c.262+8C>A | Splice Region (SNP) | VAF 142/293 reads (48%) | called by muse, mutect2, varscan2
- PER2 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PGAP1 | c.1926dup p.V643Cfs*5 | Frame Shift Ins (INS) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- PLCB1 | c.1377G>T p.M459I | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PLCD4 | c.1770T>G p.D590E | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PLEKHA4 | c.1060C>A p.L354M | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- POLQ | c.6829C>G p.L2277V | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- POLR2D | c.283T>A p.F95I | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLR3A | c.3969G>C p.K1323N | Missense Mutation (SNP) | VAF 98/606 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- POTEJ | c.1958T>C p.L653P | Missense Mutation (SNP) | VAF 206/843 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- PPP1CC | c.77A>T p.K26M | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PPP1R12A | c.2461+1G>A p.X821_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | called by muse, varscan2
- PPP1R2B | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, varscan2
- PPP1R9A | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 107/369 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PRDM4 | c.2218C>G p.L740V | Missense Mutation (SNP) | VAF 63/448 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PROM1 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- PRPF6 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 72/460 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF6 | c.1341A>C p.E447D | Missense Mutation (SNP) | VAF 250/773 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSENEN | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG5 | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PTCD2 | c.1002G>C p.E334D | Missense Mutation (SNP) | VAF 54/305 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPRB | c.2990C>G p.S997C | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- PXDNL | c.3381C>G p.F1127L | Missense Mutation (SNP) | VAF 148/260 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QARS1 | c.516+7G>T | Splice Region (SNP) | VAF 28/333 reads (8%) | called by muse, mutect2
- RAD54L | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 170/508 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RASD1 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RASGRP4 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- RBFA | c.199T>C p.S67P | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RC3H2 | c.3373_3380+37del p.X1125_splice | Splice Site (DEL) | VAF 12/140 reads (9%) | called by mutect2, pindel
- RFPL4B | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGPD3 | c.3817T>A p.L1273M | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2
- RHOT1 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT tolerated (0.79); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNASET2 | c.461T>G p.L154W | Missense Mutation (SNP) | VAF 92/444 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- RPF1 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS27A | c.169_172del p.S57Tfs*14 | Frame Shift Del (DEL) | VAF 55/439 reads (13%) | called by mutect2, pindel, varscan2
- RRNAD1 | c.1335C>G p.F445L | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYK | c.1069G>T p.D357Y (on ENST00000620660 / NM_001005861.2; = p.D354Y on NM_002958.4) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- RYR2 | c.10278C>G p.N3426K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- RYR2 | c.11880+2T>A p.X3960_splice | Splice Site (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- RYR3 | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR3 | c.9732G>C p.Q3244H (on ENST00000389232; = p.Q3245H on NM_001036.6) | Missense Mutation (SNP) | VAF 126/324 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- SALL3 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SAMD14 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SEMA6B | c.1122-1G>T p.X374_splice | Splice Site (SNP) | VAF 50/93 reads (54%) | called by muse, mutect2, varscan2
- SEMA6D | c.2288_2301del p.G763Vfs*8 (on ENST00000316364 / NM_153618.2; = p.G701Vfs*8 on NM_020858.2) | Frame Shift Del (DEL) | VAF 46/143 reads (32%) | called by mutect2, pindel, varscan2
- SERPINA7 | c.1126C>G p.P376A | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SFRP4 | c.93G>T p.M31I | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SGIP1 | c.1826C>A p.A609D | Missense Mutation (SNP) | VAF 87/292 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SH3BP2 | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SHBG | c.526C>A p.L176I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- SHE | c.993G>C p.W331C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIN3A | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); called by muse, mutect2
- SLC24A4 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC26A11 | c.1295-1G>T p.X432_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- SLC2A14 | c.277A>T p.I93L | Missense Mutation (SNP) | VAF 93/338 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- SLC30A6 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC44A5 | c.1625-1G>T p.X542_splice | Splice Site (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- SLC52A3 | c.1037C>A p.P346H | Missense Mutation (SNP) | VAF 98/423 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC9C2 | c.3040G>C p.D1014H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SLF2 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SMAP1 | c.601G>T p.E201* (on ENST00000370455 / NM_001044305.3; = p.E174* on NM_021940.5) | Nonsense Mutation (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- SMCHD1 | c.3128G>A p.S1043N | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SNAP47 | c.770A>T p.K257I | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SOX11 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by mutect2, varscan2
- SPATA31D3 | c.2700G>C p.L900F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SPICE1 | c.2471C>T p.T824I | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPRED2 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 115/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSC4D | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 91/327 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK35 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- STK38L | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRA6 | c.357dup p.D120Rfs*21 | Frame Shift Ins (INS) | VAF 129/427 reads (30%) | called by mutect2, pindel, varscan2
- STRIP2 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- SUCO | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SYNE1 | c.15914T>G p.L5305R (on ENST00000367255 / NM_182961.4; = p.L5234R on NM_033071.3) | Missense Mutation (SNP) | VAF 101/419 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TAF3 | c.1861A>T p.K621* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- TAF5 | c.621A>T p.Q207H | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- TAPT1 | c.507G>C p.L169F | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TGM6 | c.1378A>T p.R460W | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TLR5 | c.1096G>A p.D366N | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TMEM17 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 42/227 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- TMEM267 | c.456G>T p.W152C | Missense Mutation (SNP) | VAF 73/187 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- TMEM63B | c.2081G>T p.W694L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM63B | c.2082G>C p.W694C | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM74B | c.442C>G p.R148G | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- TMF1 | c.851C>G p.S284* | Nonsense Mutation (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- TMPRSS5 | c.715T>A p.F239I | Missense Mutation (SNP) | VAF 47/301 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TOPORS | c.357C>G p.C119W | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 124/365 reads (34%) | called by mutect2, pindel, varscan2
- TPGS1 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- TRGV1 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TRIL | c.1159T>G p.F387V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRIOBP | c.5116G>C p.E1706Q | Missense Mutation (SNP) | VAF 214/551 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TRMT1L | c.1582G>A p.G528R | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPS1 | c.1438G>T p.V480F (on ENST00000220888 / NM_001330599.2; = p.V493F on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 270/572 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- TRPS1 | c.244G>T p.E82* (on ENST00000220888 / NM_001330599.2; = p.E95* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 241/434 reads (56%) | called by muse, mutect2, varscan2
- TSSK2 | c.804C>G p.S268R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.01); called by muse, mutect2
- TUB | c.935A>G p.Y312C (on ENST00000299506 / NM_177972.3; = p.Y367C on NM_003320.4) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UHRF1BP1L | c.1821G>A p.M607I | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, varscan2
- USH2A | c.6739C>T p.P2247S | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- USP48 | c.2485C>G p.P829A | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VILL | c.2547G>C p.E849D | Missense Mutation (SNP) | VAF 94/201 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- VPS13A | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- VPS13C | c.757G>T p.D253Y (on ENST00000644861 / NM_020821.3; = p.D210Y on NM_017684.5) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- VSIR | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.2383G>T p.V795F | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- XIRP2 | c.6520C>A p.P2174T (on ENST00000628543; = p.P2349T on NM_152381.6) | Missense Mutation (SNP) | VAF 73/292 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZFHX4 | c.1762C>T p.P588S | Missense Mutation (SNP) | VAF 118/254 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFP36L2 | c.1301C>G p.P434R | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZMYND12 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 114/224 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- ZNF267 | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF512B | c.1560_1568del p.K521_L523del | In Frame Del (DEL) | VAF 106/376 reads (28%) | called by mutect2, pindel, varscan2
- ZNF548 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 85/230 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ZNF549 | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 144/341 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF675 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 112/278 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZNF747 | c.338C>G p.S113W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF777 | c.1722C>A p.Y574* | Nonsense Mutation (SNP) | VAF 150/440 reads (34%) | called by muse, mutect2, varscan2
- A2ML1 | c.3822C>A p.R1274= | Silent (SNP) | VAF 59/230 reads (26%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2481G>A p.T827= | Silent (SNP) | VAF 113/347 reads (33%) | catalogued as rs751110845, COSV55445014; called by muse, mutect2, varscan2
- AHNAK2 | c.3009C>T p.F1003= | Silent (SNP) | VAF 186/477 reads (39%) | called by muse, mutect2, varscan2
- ALG10B | c.1239G>T p.L413= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- APOB | c.5118A>T p.T1706= | Silent (SNP) | VAF 38/133 reads (29%) | called by muse, mutect2, varscan2
- ARAP2 | c.2476C>T p.L826= | Silent (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- ARNTL2 | c.855G>T p.R285= | Silent (SNP) | VAF 51/344 reads (15%) | catalogued as rs1464247163; called by muse, mutect2, varscan2
- ATP6V0A4 | c.606T>C p.S202= | Silent (SNP) | VAF 96/445 reads (22%) | called by muse, mutect2, varscan2
- ATP6V0B | c.534C>T p.I178= | Silent (SNP) | VAF 77/647 reads (12%) | catalogued as rs769391912, COSV52543596; called by muse, mutect2, varscan2
- BAHCC1 | c.5520G>A p.V1840= | Silent (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- BAZ2B | c.4545A>T p.A1515= | Silent (SNP) | VAF 80/291 reads (27%) | called by muse, mutect2, varscan2
- BIN2 | c.57G>A p.K19= | Silent (SNP) | VAF 35/214 reads (16%) | catalogued as COSV53331303; called by muse, mutect2, varscan2
- BMP6 | c.1170G>A p.Q390= | Silent (SNP) | VAF 115/559 reads (21%) | called by muse, mutect2, varscan2
- BNC1 | c.1992C>G p.P664= | Silent (SNP) | VAF 257/423 reads (61%) | called by muse, mutect2, varscan2
- C1orf94 | c.756G>A p.K252= (on ENST00000488417 / NM_001134734.2; = p.K62= on NM_032884.5) | Silent (SNP) | VAF 56/445 reads (13%) | catalogued as rs1476602930, COSV64914272; called by muse, mutect2, varscan2
- C5orf38 | c.108C>T p.L36= | Silent (SNP) | VAF 82/185 reads (44%) | catalogued as rs982847102, COSV57412597; called by muse, mutect2, varscan2
- CBX4 | c.774G>A p.K258= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- CCDC166 | c.930C>A p.T310= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- CD1C | c.24G>T p.L8= | Silent (SNP) | VAF 58/244 reads (24%) | catalogued as COSV63806237; called by muse, mutect2, varscan2
- CENPU | c.753G>A p.L251= | Silent (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- CHIA | c.150C>A p.L50= | Silent (SNP) | VAF 80/520 reads (15%) | catalogued as COSV58477857; called by muse, mutect2, varscan2
- CLTC | c.3231C>G p.V1077= | Silent (SNP) | VAF 24/116 reads (21%) | called by muse, mutect2
- CRAMP1 | c.2277C>T p.P759= | Silent (SNP) | VAF 33/335 reads (10%) | catalogued as rs373569007; called by muse, mutect2
- CSMD1 | c.33C>T p.L11= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as rs749085555; called by muse, mutect2, varscan2
- CTNND1 | c.1911G>A p.E637= (on ENST00000399050 / NM_001085458.2; = p.E631= on NM_001331.3) | Silent (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
- CWH43 | c.1935C>T p.I645= | Silent (SNP) | VAF 56/195 reads (29%) | catalogued as COSV56940696; called by muse, mutect2, varscan2
- DCAF4L2 | c.993C>G p.A331= | Silent (SNP) | VAF 81/170 reads (48%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.267G>C p.V89= | Silent (SNP) | VAF 241/433 reads (56%) | called by muse, mutect2, varscan2
- DFFA | c.555G>A p.V185= | Silent (SNP) | VAF 37/322 reads (11%) | catalogued as rs1557793452; called by muse, mutect2, varscan2
- DICER1 | c.183C>T p.I61= | Silent (SNP) | VAF 77/205 reads (38%) | catalogued as rs932113852, COSV100601984; ClinVar: likely benign; called by muse, mutect2, varscan2
- DISP1 | c.1143G>T p.L381= | Silent (SNP) | VAF 41/168 reads (24%) | called by muse, mutect2, varscan2
- DNAH5 | c.7572C>A p.P2524= | Silent (SNP) | VAF 90/209 reads (43%) | catalogued as COSV54249252; called by muse, mutect2, varscan2
- DNAJC11 | c.57G>A p.L19= | Silent (SNP) | VAF 63/405 reads (16%) | catalogued as rs1402193771; called by muse, mutect2, varscan2
- DRD1 | c.108C>T p.S36= | Silent (SNP) | VAF 55/289 reads (19%) | catalogued as rs1421910877; called by muse, mutect2, varscan2
- DST | c.14850A>G p.L4950= (on ENST00000361203 / NM_001374722.1; = p.L2538= on NM_015548.5) | Silent (SNP) | VAF 36/95 reads (38%) | called by muse, mutect2, varscan2
- EHMT1 | c.1065G>A p.E355= | Silent (SNP) | VAF 97/229 reads (42%) | catalogued as rs768149187; called by muse, mutect2, varscan2
- ELOA | c.519C>T p.H173= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as rs563938357; called by muse, mutect2, varscan2
- FAM168B | c.294A>G p.A98= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- FBXO17 | c.420G>T p.V140= | Silent (SNP) | VAF 59/152 reads (39%) | called by muse, mutect2, varscan2
- FLT4 | c.1677C>A p.T559= | Silent (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- FSCB | c.2370C>T p.I790= | Silent (SNP) | VAF 51/154 reads (33%) | catalogued as rs868856972; called by muse, mutect2, varscan2
- FSHR | c.1557C>A p.P519= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as COSV58624356; called by muse, mutect2, varscan2
- FSTL5 | c.1932C>T p.D644= | Silent (SNP) | VAF 67/264 reads (25%) | called by muse, mutect2, varscan2
- FYCO1 | c.1638C>A p.L546= | Silent (SNP) | VAF 286/558 reads (51%) | called by mutect2, varscan2
- GGT7 | c.639C>A p.L213= | Silent (SNP) | VAF 24/107 reads (22%) | called by muse, mutect2, varscan2
- GJA3 | c.783G>T p.P261= | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, varscan2
- GLIPR1L1 | c.432C>A p.A144= | Silent (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- GON4L | c.1551C>T p.D517= | Silent (SNP) | VAF 97/353 reads (27%) | catalogued as rs577681763; called by muse, mutect2, varscan2
- GPR78 | c.360G>C p.P120= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- GRM3 | c.117T>A p.L39= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100862373; called by muse, mutect2, varscan2
- HECW1 | c.159C>G p.L53= | Silent (SNP) | VAF 152/478 reads (32%) | called by muse, mutect2, varscan2
- HECW1 | c.508C>T p.L170= | Silent (SNP) | VAF 61/181 reads (34%) | called by muse, mutect2, varscan2
- HGS | c.144C>A p.S48= | Silent (SNP) | VAF 73/308 reads (24%) | catalogued as COSV100230652; called by muse, mutect2, varscan2
- HSPH1 | c.2076G>A p.L692= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- IFRD1 | c.1080T>G p.P360= | Silent (SNP) | VAF 61/444 reads (14%) | called by muse, mutect2, varscan2
- IGKV1-16 | c.81C>A p.T27= | Silent (SNP) | VAF 164/709 reads (23%) | catalogued as rs755568625; called by muse, varscan2
- IGKV1D-17 | c.300G>C p.L100= | Silent (SNP) | VAF 116/618 reads (19%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.231C>A p.S77= | Silent (SNP) | VAF 83/286 reads (29%) | called by muse, mutect2, varscan2
- JARID2 | c.420A>T p.P140= | Silent (SNP) | VAF 143/316 reads (45%) | catalogued as COSV59190118; called by muse, mutect2, varscan2
- KCNA10 | c.789C>A p.S263= | Silent (SNP) | VAF 117/410 reads (29%) | called by muse, mutect2, varscan2
- KCNT2 | c.414A>T p.I138= | Silent (SNP) | VAF 23/136 reads (17%) | called by muse, mutect2, varscan2
- KCNV1 | c.570C>T p.P190= | Silent (SNP) | VAF 198/403 reads (49%) | called by muse, mutect2, varscan2
- KIR2DL1 | c.234T>C p.D78= | Silent (SNP) | VAF 161/896 reads (18%) | catalogued as COSV52409706; called by muse, mutect2, varscan2
- KLHL32 | c.1269G>A p.K423= | Silent (SNP) | VAF 170/448 reads (38%) | called by muse, mutect2, varscan2
- KMT2D | c.15669T>C p.N5223= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- LAMC2 | c.1458C>A p.P486= | Silent (SNP) | VAF 57/333 reads (17%) | catalogued as COSV51454509, COSV99917774; called by muse, mutect2, varscan2
- LCTL | c.135G>A p.V45= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV58422747; called by muse, mutect2, varscan2
- LIG4 | c.1086T>C p.T362= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- LRRC7 | c.405C>T p.L135= (on ENST00000651989 / NM_001370785.2; = p.L102= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs760688435; called by muse, mutect2, varscan2
- LTO1 | c.312A>G p.E104= | Silent (SNP) | VAF 17/125 reads (14%) | called by muse, mutect2, varscan2
- MAB21L2 | c.585C>A p.P195= | Silent (SNP) | VAF 57/150 reads (38%) | called by muse, mutect2, varscan2
- MACF1 | c.11031C>G p.V3677= (on ENST00000372915; = p.V1610= on NM_012090.5) | Silent (SNP) | VAF 57/239 reads (24%) | catalogued as COSV57129088, COSV99243397; called by muse, mutect2, varscan2
- MEIOC | c.330T>G p.P110= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- MRPL47 | c.252A>G p.A84= | Silent (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2, varscan2
- MYH14 | c.627G>A p.K209= | Silent (SNP) | VAF 120/315 reads (38%) | called by muse, mutect2, varscan2
- MYH2 | c.1692C>A p.A564= | Silent (SNP) | VAF 63/164 reads (38%) | called by muse, mutect2, varscan2
- MYMK | c.258C>T p.A86= | Silent (SNP) | VAF 186/262 reads (71%) | catalogued as rs1474695498; called by muse, mutect2, varscan2
- NFAT5 | c.1158G>A p.G386= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV100591177; called by muse, mutect2, varscan2
- NLGN1 | c.1294T>C p.L432= | Silent (SNP) | VAF 46/166 reads (28%) | called by muse, mutect2, varscan2
- NOL4L | c.657C>T p.I219= | Silent (SNP) | VAF 39/304 reads (13%) | catalogued as COSV62890270; called by muse, mutect2, varscan2
- NR2E3 | c.1053G>A p.V351= | Silent (SNP) | VAF 60/189 reads (32%) | called by muse, mutect2, varscan2
- OGFOD2 | c.30C>T p.F10= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as rs776090100, COSV57441881; called by muse, mutect2, varscan2
- OR10J3 | c.750C>A p.I250= | Silent (SNP) | VAF 123/370 reads (33%) | called by muse, mutect2, varscan2
- OR2T33 | c.585C>T p.N195= | Silent (SNP) | VAF 54/439 reads (12%) | catalogued as rs1405110714, COSV58815244; called by muse, mutect2, varscan2
- OR4A5 | c.393G>A p.L131= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs767755671, COSV60521612; called by muse, mutect2, varscan2
- OR4C11 | c.426G>T p.L142= | Silent (SNP) | VAF 19/89 reads (21%) | called by muse, mutect2, varscan2
- OR51A7 | c.159C>A p.P53= | Silent (SNP) | VAF 22/131 reads (17%) | called by muse, mutect2, varscan2
- OR8B8 | c.672C>T p.S224= | Silent (SNP) | VAF 82/227 reads (36%) | called by muse, mutect2, varscan2
- PANX1 | c.807C>A p.A269= | Silent (SNP) | VAF 73/183 reads (40%) | called by muse, mutect2, varscan2
- PCDHB15 | c.1347C>T p.P449= | Silent (SNP) | VAF 73/400 reads (18%) | catalogued as rs782729594, COSV50858234; called by muse, mutect2, varscan2
- PCDHGA12 | c.543C>T p.I181= | Silent (SNP) | VAF 99/211 reads (47%) | catalogued as rs1296142784, COSV52766919; called by muse, mutect2, varscan2
- PDZD3 | c.1212C>T p.V404= (on ENST00000531114; = p.V324= on NM_024791.4) | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- PFKM | c.2178G>A p.L726= | Silent (SNP) | VAF 108/616 reads (18%) | called by muse, mutect2, varscan2
- PFN2 | c.354G>T p.G118= | Silent (SNP) | VAF 43/309 reads (14%) | catalogued as rs774638789; called by muse, mutect2, varscan2
- PGM2L1 | c.522C>T p.A174= | Silent (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- PIEZO2 | c.2976G>T p.V992= | Silent (SNP) | VAF 49/265 reads (18%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1362C>T p.P454= | Silent (SNP) | VAF 58/353 reads (16%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.900G>T p.L300= | Silent (SNP) | VAF 47/340 reads (14%) | called by muse, mutect2, varscan2
- PJA1 | c.1404G>A p.E468= (on ENST00000361478 / NM_145119.4; = p.E280= on NM_022368.5) | Silent (SNP) | VAF 95/186 reads (51%) | catalogued as rs1310760541; called by muse, mutect2, varscan2
- PLAA | c.390A>C p.S130= | Silent (SNP) | VAF 146/259 reads (56%) | catalogued as rs1353019645; called by muse, varscan2
- PLCG1 | c.60C>T p.A20= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- PLCH1 | c.3963G>A p.K1321= (on ENST00000340059 / NM_001130960.2; = p.K1313= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/276 reads (29%) | called by muse, mutect2, varscan2
- POLR1A | c.4317G>A p.E1439= | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- POM121C | c.48G>A p.P16= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs1349278029; called by muse, mutect2, varscan2
- PPM1N | c.336C>A p.R112= | Silent (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- PRDX1 | c.276G>A p.K92= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV99423659; called by muse, mutect2, varscan2
- PRSS1 | c.84C>T p.Y28= | Silent (SNP) | VAF 66/518 reads (13%) | called by muse, varscan2
- PTPRO | c.2013T>A p.V671= | Silent (SNP) | VAF 36/251 reads (14%) | catalogued as COSV99839635; called by muse, mutect2, varscan2
- RAB6D | c.360C>A p.I120= | Silent (SNP) | VAF 27/372 reads (7%) | called by muse, mutect2
- RBBP6 | c.3528G>A p.V1176= | Silent (SNP) | VAF 63/149 reads (42%) | called by muse, mutect2, varscan2
- RFPL4B | c.294C>A p.T98= | Silent (SNP) | VAF 81/208 reads (39%) | catalogued as rs770217543; called by muse, mutect2, varscan2
- RHBDL1 | c.1122C>T p.F374= (on ENST00000219551 / NM_001318733.2; = p.F309= on NM_001278720.2) | Silent (SNP) | VAF 28/73 reads (38%) | called by muse, mutect2, varscan2
- RNF213 | c.1089A>G p.A363= | Silent (SNP) | VAF 78/517 reads (15%) | called by muse, mutect2, varscan2
- RNF31 | c.1269G>C p.S423= | Silent (SNP) | VAF 53/151 reads (35%) | called by muse, mutect2, varscan2
- SAMD4A | c.996G>A p.L332= | Silent (SNP) | VAF 76/179 reads (42%) | called by muse, mutect2, varscan2
- SCD5 | c.24G>A p.A8= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- SDK2 | c.804G>T p.R268= | Silent (SNP) | VAF 78/296 reads (26%) | catalogued as rs1021414586; called by muse, mutect2, varscan2
- SETX | c.6738C>A p.I2246= | Silent (SNP) | VAF 101/245 reads (41%) | called by muse, mutect2, varscan2
- SF3A3 | c.1272A>C p.R424= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- SLC20A1 | c.630C>G p.L210= | Silent (SNP) | VAF 65/175 reads (37%) | catalogued as rs760656466; called by muse, mutect2, varscan2
- SLC22A23 | c.621C>T p.I207= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- SLC2A14 | c.993C>A p.A331= | Silent (SNP) | VAF 33/313 reads (11%) | called by muse, mutect2, varscan2
- SLC4A9 | c.171C>T p.F57= | Silent (SNP) | VAF 99/288 reads (34%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.429C>T p.G143= | Silent (SNP) | VAF 45/479 reads (9%) | catalogued as rs1370522295; called by muse, mutect2
- SLITRK3 | c.2808C>G p.L936= | Silent (SNP) | VAF 81/259 reads (31%) | catalogued as COSV53854412; called by muse, mutect2, varscan2
- SNRNP200 | c.4713C>A p.L1571= | Silent (SNP) | VAF 150/434 reads (35%) | called by muse, mutect2, varscan2
- SNTG1 | c.1050G>T p.L350= | Silent (SNP) | VAF 225/417 reads (54%) | catalogued as COSV52466797; called by muse, mutect2, varscan2
- SORCS3 | c.759C>T p.L253= | Silent (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- SPIRE2 | c.261C>T p.V87= | Silent (SNP) | VAF 26/344 reads (8%) | catalogued as rs1356844262, COSV65555578; called by muse, mutect2
- ST14 | c.1161G>A p.L387= | Silent (SNP) | VAF 125/385 reads (32%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2862T>C p.S954= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- SUGCT | c.60G>T p.R20= | Silent (SNP) | VAF 62/207 reads (30%) | called by muse, mutect2, varscan2
- SULT2A1 | c.66C>T p.T22= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs755438669, COSV99705461; called by muse, mutect2, varscan2
- SYNE1 | c.21318G>A p.E7106= (on ENST00000367255 / NM_182961.4; = p.E7035= on NM_033071.3) | Silent (SNP) | VAF 115/385 reads (30%) | called by muse, mutect2, varscan2
- TAF1L | c.5277C>A p.V1759= | Silent (SNP) | VAF 123/342 reads (36%) | called by muse, mutect2, varscan2
- TMC2 | c.2016C>T p.C672= | Silent (SNP) | VAF 68/367 reads (19%) | called by muse, mutect2, varscan2
- TRIM51GP | c.774G>T p.L258= | Silent (SNP) | VAF 50/282 reads (18%) | called by muse, mutect2, varscan2
- TRIM58 | c.1257C>A p.A419= | Silent (SNP) | VAF 82/266 reads (31%) | called by muse, mutect2, varscan2
- TRPM2 | c.2281C>T p.L761= | Silent (SNP) | VAF 149/264 reads (56%) | catalogued as rs1221973333; called by muse, mutect2, varscan2
- TTN | c.68334T>A p.A22778= (on ENST00000591111; = p.A15354= on NM_003319.4) | Silent (SNP) | VAF 45/162 reads (28%) | catalogued as rs199572059, COSV59968259, COSV60422623; called by muse, mutect2, varscan2
- TTN | c.63222C>T p.T21074= (on ENST00000591111; = p.T13650= on NM_003319.4) | Silent (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- VGF | c.841C>A p.R281= | Silent (SNP) | VAF 15/61 reads (25%) | called by muse, mutect2, varscan2
- VGF | c.840C>A p.R280= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- VWC2L | c.510C>T p.V170= | Silent (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- VWDE | c.3132C>T p.L1044= | Silent (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- VXN | c.30C>T p.D10= | Silent (SNP) | VAF 98/207 reads (47%) | catalogued as rs772457629; called by muse, mutect2, varscan2
- WDR11 | c.1077C>T p.F359= | Silent (SNP) | VAF 44/298 reads (15%) | called by muse, mutect2, varscan2
- WDR19 | c.1416G>T p.V472= | Silent (SNP) | VAF 41/209 reads (20%) | called by muse, mutect2, varscan2
- WNK2 | c.3840C>T p.L1280= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV99940776; called by muse, mutect2, varscan2
- XKR5 | c.51G>A p.Q17= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- ZFHX3 | c.6273G>A p.P2091= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs747711659, COSV51719710; called by muse, mutect2, varscan2
- ZNF324B | c.570G>A p.R190= | Silent (SNP) | VAF 120/255 reads (47%) | called by muse, mutect2, varscan2
- ZNF616 | c.2196C>T p.L732= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as COSV57510287; called by muse, mutect2, varscan2
- ZNF644 | c.12C>T p.F4= | Silent (SNP) | VAF 93/307 reads (30%) | called by muse, mutect2, varscan2
- ZYG11B | c.1506G>A p.K502= | Silent (SNP) | VAF 8/63 reads (13%) | called by muse, mutect2
- ABCC9 | chr12:21801103 C>T | 3'Flank (SNP) | VAF 82/255 reads (32%) | called by muse, mutect2, varscan2
- AC004947.2 | n.81C>G | RNA (SNP) | VAF 61/223 reads (27%) | called by muse, mutect2, varscan2
- AC011525.1 | n.1048C>A | RNA (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2
- AC011773.3 | n.668-3679_668-3661del | Intron (DEL) | VAF 55/148 reads (37%) | called by mutect2, pindel, varscan2
- AC098591.2 | n.597C>T | RNA (SNP) | VAF 141/402 reads (35%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1625C>T | RNA (SNP) | VAF 72/258 reads (28%) | catalogued as rs1559548042; called by muse, mutect2, varscan2
- ACTG1P17 | n.657G>T | RNA (SNP) | VAF 149/223 reads (67%) | called by muse, mutect2, varscan2
- ACTG1P17 | n.656G>A | RNA (SNP) | VAF 151/223 reads (68%) | called by muse, mutect2, varscan2
- ACTG1P17 | n.518C>T | RNA (SNP) | VAF 39/60 reads (65%) | called by muse, mutect2, varscan2
- ADAR | c.-909C>G | 5'UTR (SNP) | VAF 34/339 reads (10%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826756 C>G | 3'Flank (SNP) | VAF 58/103 reads (56%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846110 G>C | 5'Flank (SNP) | VAF 47/83 reads (57%) | catalogued as rs1241672449; called by muse, mutect2, varscan2
- ALG1 | chr16:5071824 C>T | 5'Flank (SNP) | VAF 75/191 reads (39%) | called by muse, mutect2, varscan2
- ANXA11 | c.1459-512G>T | Intron (SNP) | VAF 25/167 reads (15%) | called by muse, varscan2
- ANXA2P2 | n.183C>A | RNA (SNP) | VAF 131/296 reads (44%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499895 G>C | 5'Flank (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- ATG4B | c.538+87C>T | Intron (SNP) | VAF 39/232 reads (17%) | catalogued as rs768916325; called by muse, mutect2, varscan2
- BAG5 | c.-21G>A | 5'UTR (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- BANF1 | c.*19C>G | 3'UTR (SNP) | VAF 79/385 reads (21%) | called by muse, mutect2, varscan2
- BLK | c.1030-515C>G | Intron (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- BRCA1 | c.*174G>C | 3'UTR (SNP) | VAF 26/332 reads (8%) | called by muse, mutect2
- BTBD19 | c.*24G>T | 3'UTR (SNP) | VAF 79/283 reads (28%) | called by muse, mutect2, varscan2
- C4B | chr6:32009826 C>G | 5'Flank (SNP) | VAF 150/336 reads (45%) | called by muse, mutect2, varscan2
- C9orf163 | n.1374C>T | RNA (SNP) | VAF 45/123 reads (37%) | catalogued as rs202084159; called by muse, mutect2, varscan2
- CAVIN3 | c.385-49G>C | Intron (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- CCS | c.-71C>T | 5'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- CHCHD2 | c.-5C>T | 5'UTR (SNP) | VAF 27/335 reads (8%) | catalogued as rs1210195060; called by muse, mutect2
- CHCHD4 | c.22+2594G>C | Intron (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- CLTCL1 | c.-20G>T | 5'UTR (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- CWC27 | c.938+3231G>C | Intron (SNP) | VAF 27/110 reads (25%) | called by muse, mutect2, varscan2
- DISP3 | c.3376-593G>C | Intron (SNP) | VAF 34/221 reads (15%) | catalogued as rs1302145804; called by muse, mutect2, varscan2
- DMPK | c.1648-13C>G | Intron (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2, varscan2
- FBRS | chr16:30659941 C>T | 5'Flank (SNP) | VAF 112/251 reads (45%) | catalogued as rs1316442136; called by muse, varscan2
- FRMD8P1 | n.1020C>G | RNA (SNP) | VAF 31/98 reads (32%) | called by muse, mutect2, varscan2
- FSHR | c.374+2579G>A | Intron (SNP) | VAF 35/259 reads (14%) | called by muse, mutect2
- GABARAPL1 | c.*11G>A | 3'UTR (SNP) | VAF 35/182 reads (19%) | called by muse, mutect2, varscan2
- GATD1 | c.*41C>T | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.*38G>C | 3'UTR (SNP) | VAF 45/208 reads (22%) | catalogued as rs1301505364; called by muse, mutect2, varscan2
- HDAC8 | c.738-9930T>G | Intron (SNP) | VAF 87/137 reads (64%) | called by muse, mutect2, varscan2
- IGKV1-13 | n.345A>T | RNA (SNP) | VAF 76/968 reads (8%) | called by muse, mutect2
- LAMP1 | c.-6C>G | 5'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- LDLR | c.-41C>G | 5'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- LINC00840 | n.377C>G | RNA (SNP) | VAF 100/372 reads (27%) | called by muse, mutect2, varscan2
- LINC01193 | n.1329T>G | RNA (SNP) | VAF 30/251 reads (12%) | called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.-493+10509G>C | Intron (SNP) | VAF 57/240 reads (24%) | called by muse, mutect2, varscan2
- LPL | c.249+35del | Intron (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- MAEA | c.70-2307G>T | Intron (SNP) | VAF 21/97 reads (22%) | catalogued as COSV53265465; called by muse, mutect2, varscan2
- MDM2 | c.174+980C>G | Intron (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2
- MEIS1 | c.1114+29C>A | Intron (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2
- MIR543 | n.2A>G | RNA (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- MMP14 | c.108+332C>T | Intron (SNP) | VAF 102/275 reads (37%) | called by muse, mutect2, varscan2
- MYB | c.*45G>C | 3'UTR (SNP) | VAF 35/165 reads (21%) | called by muse, mutect2, varscan2
- NCAM1 | c.-94A>T | 5'UTR (SNP) | VAF 155/458 reads (34%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.414G>A | RNA (SNP) | VAF 93/466 reads (20%) | catalogued as rs751713504; called by muse, mutect2, varscan2
- NSG2 | c.*79A>G | 3'UTR (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- OPRM1 | c.1165-10895C>G | Intron (SNP) | VAF 44/216 reads (20%) | catalogued as rs375186402; called by mutect2, varscan2
- PANK4 | c.125-20G>A | Intron (SNP) | VAF 34/136 reads (25%) | catalogued as rs1232564453; called by muse, mutect2
- PCDHGB3 | c.2415+26C>A | Intron (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- PDE6B | c.927+167G>T | Intron (SNP) | VAF 23/109 reads (21%) | called by muse, mutect2, varscan2
- PHF19 | c.465+39C>T | Intron (SNP) | VAF 201/482 reads (42%) | catalogued as rs1212180646; called by muse, mutect2, varscan2
- PLEKHA7 | chr11:16786336 C>T | 3'Flank (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- PLXNA1 | c.4363-241C>T | Intron (SNP) | VAF 66/249 reads (27%) | catalogued as rs1485497919; called by muse, mutect2, varscan2
- PRKN | c.1083+3417T>A | Intron (SNP) | VAF 54/217 reads (25%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12859C>T | Intron (SNP) | VAF 68/185 reads (37%) | called by muse, mutect2, varscan2
- RBM39 | c.52-35C>T | Intron (SNP) | VAF 68/424 reads (16%) | catalogued as rs753692993; called by muse, mutect2, varscan2
- RBMS1 | c.901-942A>C | Intron (SNP) | VAF 21/333 reads (6%) | catalogued as COSV100816740; called by muse, mutect2
- RN7SL759P | chr15:20568381 G>C | 5'Flank (SNP) | VAF 22/116 reads (19%) | catalogued as rs1218421720; called by mutect2, varscan2
- RNF32 | chr7:156640647 G>T | 5'Flank (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- SCARB2 | c.1188-28G>A | Intron (SNP) | VAF 97/341 reads (28%) | called by muse, mutect2, varscan2
- SCN8A | c.1998+10G>C | Intron (SNP) | VAF 127/404 reads (31%) | catalogued as rs755729617; called by muse, mutect2, varscan2
- SEC22C | c.*4564G>T | 3'UTR (SNP) | VAF 75/130 reads (58%) | called by muse, mutect2, varscan2
- SESTD1 | c.255+2037A>G | Intron (SNP) | VAF 25/123 reads (20%) | catalogued as rs1335560993; called by muse, mutect2, varscan2
- SH3TC1 | c.3405+10C>A | Intron (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- SHROOM3 | c.5198+34_5198+35del | Intron (DEL) | VAF 38/335 reads (11%) | called by mutect2, pindel, varscan2
- SLC7A11 | c.*27C>T | 3'UTR (SNP) | VAF 42/120 reads (35%) | catalogued as COSV54929077; called by muse, mutect2, varscan2
- SLIT2 | c.2725+341G>T | Intron (SNP) | VAF 37/276 reads (13%) | called by muse, mutect2, varscan2
- SMIM8 | n.628A>T | RNA (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088231 A>G | 3'Flank (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- SORBS2 | c.-194G>C | 5'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- SSPOP | n.3939G>A | RNA (SNP) | VAF 105/335 reads (31%) | called by muse, mutect2, varscan2
- STIP1 | chr11:64185956 T>A | 5'Flank (SNP) | VAF 18/101 reads (18%) | catalogued as rs766346488; called by muse, mutect2, varscan2
- STOM | c.-8C>A | 5'UTR (SNP) | VAF 54/132 reads (41%) | called by muse, mutect2, varscan2
- TBXA2R | c.*786A>T | 3'UTR (SNP) | VAF 136/291 reads (47%) | called by muse, mutect2, varscan2
- USP32P1 | n.334+873G>C | Intron (SNP) | VAF 150/770 reads (19%) | called by muse, mutect2, varscan2
- UTRN | c.7480-18203A>T | Intron (SNP) | VAF 49/179 reads (27%) | called by muse, mutect2, varscan2
- VAMP2 | c.*35C>T | 3'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, varscan2
- WDR86 | c.163+428G>A | Intron (SNP) | VAF 124/482 reads (26%) | catalogued as rs1373779522; called by muse, mutect2, varscan2
- XIRP2 | c.*154T>C | 3'UTR (SNP) | VAF 34/180 reads (19%) | called by muse, mutect2, varscan2
- Z98752.3 | c.201+7379G>C | Intron (SNP) | VAF 94/306 reads (31%) | called by muse, mutect2, varscan2
- ZEB1 | c.58+43717G>T | Intron (SNP) | VAF 80/262 reads (31%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451491 G>T | 5'Flank (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- ZNF799 | c.-37C>G | 5'UTR (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- ZNF849P | n.635G>T | RNA (SNP) | VAF 105/272 reads (39%) | catalogued as rs368652341; called by muse, mutect2, varscan2
